Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00K, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00K-01A (Primary Tumor).

Sample ID #:

Diagnosis:

Resectate of the colon (sigmoid colon) with tumor-free oral and aboral resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and without regional lymph node metastases (G2, pT3 L0 V0 R0 pN0 0/55).

1CD-0-3

Adenocarcinoma, NOS 8146/3

Site: Sigmoid colon c18.7 hr 3/30/11

Primary Discrepancy		☒
HIPAA Discrepancy History		☒
Reviewer Initials	km	Sheth

Source: NCI Genomic Data Commons file d0e8d5d9-6297-4999-8359-7d8a8fab5561 (TCGA-AA-A00K.28B20E9A-DFF6-400D-91FE-05285D277AC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).